Gene-level copy-number profile of tumor specimen HCM-BROD-0095-C15-06A from HCMI case HCM-BROD-0095-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 51.5 years (18,799 days).
Specimen HCM-BROD-0095-C15-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5eded3c6-06eb-4494-a675-e3002c5d110a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0095-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,735 have no estimate.
https://portal.gdc.cancer.gov/files/9b540b4d-18bf-4ebd-a70c-090aae083a26

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 531; copy number 1: 4,426; copy number 2: 35,549; copy number 3: 11,870; copy number 4: 5,015; copy number 5: 1,315; copy number 6: 156; copy number 7: 15; copy number 9: 11.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:137,682–195,411, 8 genes: AL627309.7, AL627309.2, AL627309.5, RNU6-1100P, AL627309.4, FO538757.1, WASH9P, MIR6859-2.
- chr1:587,629–634,922, 9 genes (within-gene range 0–1): AC114498.1, MTND1P23, MTND2P28, MTCO1P12, AC114498.2, MTCO2P12, MTATP8P1, MTATP6P1, MTCO3P12.
- chr15:34,415,450–34,495,900, 3 genes (within-gene range 0–1): AC025678.3, HNRNPLP2, FSCN1P1.
- chr16:78,355,529–78,506,568, 2 genes (within-gene range 0–2): LSM3P5, AC046158.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,497 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,177,234–112,711,433, 15 genes, copy number 5 (within-gene range 2–5): LINC02884, TXNP3, AL591521.1, CTTNBP2NL, MIR4256, WNT2B, AL354760.1, ST7L, CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1, RHOC, AL603832.3.
- chr1:119,533,749–121,580,524, 57 genes, copy number 6: GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:179,025,804–196,795,407, 235 genes, copy number 5 (broad region; genes not listed).
- chr1:238,107,736–248,937,043, 249 genes, copy number 5 (broad region; genes not listed).
- chr2:207,529,737–207,769,906, 11 genes, copy number 9 (within-gene range 4–9): CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5.
- chr3:7,951,263–8,963,773, 13 genes, copy number 5: LMCD1-AS1, AC018832.1, AC023481.1, RNU4ATAC17P, LMCD1, AC034187.1, SSUH2, OR7E122P, CAV3, OXTR, RAD18, AC034186.2, AC034186.1.
- chr7:81,946,444–84,940,256, 18 genes, copy number 5 (within-gene range 5–7): CACNA2D1, CACNA2D1-AS1, MTHFD2P5, AC004006.1, PCLO, RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2, SEMA3A, RPL7P30, AC003984.1, AC093716.1, HMGN2P11, AC074183.2, AC074183.1.
- chr7:87,627,548–104,208,047, 388 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:112,148,742–132,760,712, 239 genes, copy number 5 (broad region; genes not listed).
- chr8:140,657,900–141,518,737, 23 genes, copy number 5 (within-gene range 4–5): PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3, AC011676.4, LINC01300, AC100803.3, GPR20, AC100803.2, PTP4A3, MROH5, AC100803.4, AC100803.1, HNRNPA1P38, AC138647.1.
- chr12:273,954–563,509, 4 genes, copy number 5: AC007406.4, KDM5A, CCDC77, B4GALNT3.
- chr17:26,981,694–31,095,450, 232 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:53,544,615–54,269,542, 13 genes, copy number 5: Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, PFDN4, AL133335.1.

Autosomal genes at a single copy (total copy number 1): 2,079. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
